BEATAML1.0 case 2512 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myelodysplastic Syndromes; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/2f7daeaf-43b0-44ce-baca-09a9cb18ea6c

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Refractory anemia with excess blasts: ICD-O-3 morphology code: 9983/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,180 days); Progression or recurrence: no; ELN risk classification: Intermediate.

Biospecimens (2 samples)
- Sample BA2793D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample BA2998D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
